Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016343-09A.1 (aliquot TARGET-15-SJMPAL016343-09A.1-01D) from TARGET case TARGET-15-SJMPAL016343, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,198 days).
Specimen TARGET-15-SJMPAL016343-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 779994ec-bf82-4bd6-9b29-8209683d2471.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016343-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016343-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e9baff5-caf4-4d79-ae07-c297dcc6adc1

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 2, Intron 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4110+1G>A p.X1370_splice | Splice Site (SNP) | VAF 50/75 reads (67%) | catalogued as rs1555617383, CS000898, CS971829, COSV62193545, COSV62207614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GFPT2 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs748470946, COSV53806766; called by muse, mutect2, varscan2
- GPSM1 | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100696556; called by muse, mutect2
- NOTCH1 | c.5079_5080insGC p.Q1694Afs*105 | Frame Shift Ins (INS) | VAF 51/118 reads (43%) | catalogued as COSV53110775; called by mutect2, pindel*, varscan2*
- ANKAR | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2
- CASR | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, varscan2
- FAM83B | c.2110C>A p.L704M | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.905); called by muse, mutect2
- HIVEP2 | c.6583G>T p.E2195* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- INPP4B | c.890dup p.N299Kfs*7 | Frame Shift Ins (INS) | VAF 30/88 reads (34%) | called by pindel, varscan2
- NAIF1 | c.836A>G p.Q279R | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PRR3 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- HMCN2 | c.9027G>A p.S3009= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs781658046; called by muse, mutect2, varscan2
- KRTAP13-4 | c.102C>T p.A34= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV61879854; called by muse, mutect2, varscan2
- TSEN15 | c.342C>A p.L114= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- AL627230.3 | c.76-99C>T | Intron (SNP) | VAF 52/362 reads (14%) | catalogued as rs1352817288; called by muse, mutect2
- CPSF7 | c.273+245G>A | Intron (SNP) | VAF 57/141 reads (40%) | called by muse, mutect2, varscan2
